FM case AD2800 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Nevi and Melanomas.
https://portal.gdc.cancer.gov/cases/705bf21a-4509-4ca5-9595-a3d0dad253f8

Male, 75.1 years: Melanoma, NOS (ICD-O-3 8720/3); specimen biopsied or resected from the eye. Tumor nuclei on the sequenced sample's slide: 90% (pathologist estimate recorded by GDC). Sample type: Tumor.
